Somatic mutation profile of tumor specimen TCGA-AP-A05D-01A (aliquot TCGA-AP-A05D-01A-11W-A027-09) from TCGA case TCGA-AP-A05D, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 67.3 years (24,597 days).
Specimen TCGA-AP-A05D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02fdfa19-92d9-4ecf-9e09-0e578c8f5012.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A05D-10A (Blood Derived Normal), aliquot TCGA-AP-A05D-10A-01W-A027-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/434d3493-17dd-4a04-90b1-73c5eb4b0568

The open-access MAF lists 37 somatic variants for this specimen: 31 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 5, Frame Shift Del 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1034A>T p.N345I | Missense Mutation (SNP) | VAF 54/138 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519938, COSV55881772, COSV55902438, COSV55902706; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 39/89 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 45/79 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARHGAP25 | c.1834C>T p.R612C (on ENST00000409202 / NM_001007231.3; = p.R604C on NM_014882.3) | Missense Mutation (SNP) | VAF 205/531 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs942770478, COSV54903744, COSV54905907; called by muse, mutect2, varscan2
- CATSPER1 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.348); catalogued as rs758302064, COSV56411418; called by muse, mutect2, varscan2
- CDK16 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs1411375433, COSV52092165; called by muse, mutect2
- CHAMP1 | c.323G>T p.S108I | Missense Mutation (SNP) | VAF 83/485 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV63522593; called by muse, mutect2, varscan2
- CHD4 | c.2885G>A p.R962H (on ENST00000357008 / NM_001363606.2; = p.R975H on NM_001273.5) | Missense Mutation (SNP) | VAF 135/326 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58896611, COSV58901386; called by muse, mutect2, varscan2
- FOXA2 | c.517C>T p.Q173* (on ENST00000377115 / NM_153675.3; = p.Q179* on NM_021784.5) | Nonsense Mutation (SNP) | VAF 40/128 reads (31%) | catalogued as COSV65796499; called by muse, mutect2, varscan2
- GTF2B | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65137075; called by muse, mutect2, varscan2
- HSPA5 | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.022); catalogued as COSV61029402; called by muse, mutect2, varscan2
- LAMA3 | c.9641A>T p.K3214M (on ENST00000313654 / NM_198129.4; = p.K1605M on NM_000227.6) | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52536694; called by muse, mutect2
- LBHD1 | c.847C>A p.P283T (on ENST00000431002 / NM_001367940.1; = p.P257T on NM_024099.3) | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV63473145, COSV63473347; called by muse, mutect2, varscan2
- LRFN2 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs1443410484, COSV57828793; called by muse, mutect2, varscan2
- LRP6 | c.820T>G p.F274V | Missense Mutation (SNP) | VAF 243/696 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV53789171; called by muse, mutect2, varscan2
- LRRIQ1 | c.139G>T p.V47F | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV67813271, COSV67813859; called by muse, mutect2
- OAZ3 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 12/247 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV100162523; called by muse, mutect2
- PCDH19 | c.2885G>A p.R962Q (on ENST00000373034 / NM_001184880.2; = p.R914Q on NM_020766.3) | Missense Mutation (SNP) | VAF 69/281 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs779540893, COSV55265155; called by muse, mutect2, varscan2
- PCDHB15 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.686); catalogued as rs17844634, COSV50931745, COSV51003525; called by muse, mutect2, varscan2
- PDE6A | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs761022237, COSV54928350; called by muse, mutect2, varscan2
- PITX2 | c.349G>C p.E117Q (on ENST00000354925 / NM_001204397.1; = p.E124Q on NM_000325.6) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60740015, COSV60741296; called by muse, mutect2, varscan2
- PLCL2 | c.3309A>T p.E1103D (on ENST00000615277 / NM_001144382.2; = p.E977D on NM_015184.5) | Missense Mutation (SNP) | VAF 10/278 reads (4%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.014); catalogued as COSV69055808; called by muse, mutect2
- PRSS37 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV63339566; called by muse, mutect2, varscan2
- RPGRIP1L | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.712); catalogued as rs763182141, COSV50908707; called by muse, mutect2, varscan2
- SCML1 | c.382T>C p.Y128H (on ENST00000380041 / NM_001037540.3; = p.Y101H on NM_006746.6) | Missense Mutation (SNP) | VAF 134/261 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV66240825; called by muse, mutect2, varscan2
- TCERG1 | c.1955G>A p.R652Q | Missense Mutation (SNP) | VAF 83/204 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); catalogued as rs557429384, COSV57038414; called by muse, mutect2, varscan2
- TLN2 | c.226C>G p.R76G | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60887511, COSV60891001; called by muse, mutect2, varscan2
- USP15 | c.1608G>C p.M536I (on ENST00000280377 / NM_001351159.2; = p.M507I on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 107/293 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV54793853; called by muse, mutect2, varscan2
- ARHGAP6 | c.1817del p.P606Qfs*8 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel, varscan2
- ETS2 | c.1155_1161del p.G386Dfs*25 | Frame Shift Del (DEL) | VAF 37/158 reads (23%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.595G>C p.A199P | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CAPN12 | c.339C>T p.S113= | Silent (SNP) | VAF 42/84 reads (50%) | catalogued as COSV61016745; called by muse, mutect2
- CEP41 | c.228C>G p.L76= | Silent (SNP) | VAF 133/319 reads (42%) | catalogued as COSV56220160; called by muse, mutect2, varscan2
- DCST1 | c.705G>A p.S235= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as rs139035677; called by muse, mutect2, varscan2
- KRT83 | c.1458C>T p.G486= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as COSV53340791; called by muse, mutect2, varscan2
- SLC46A3 | c.264A>G p.T88= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as COSV57182363; called by muse, mutect2, varscan2
- FMN1 | c.2044-1497A>T | Intron (SNP) | VAF 4/63 reads (6%) | catalogued as COSV57925152; called by muse, mutect2
